Surgical pathology report (de-identified scan), TCGA case TCGA-49-6761, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6761-01A (Primary Tumor).

[page 1 of 4]
Data Date-Time

Printed By:

Printed On:

Order Name:

Observation Date-time:

Result Name:

Path Report

Result Status:

Final Result

1 of 4

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph node, level 7, excision:
Hyperplastic lymph node, metastatic carcinoma not identified.
- B. Lymph node, level 12, excision:
Hyperplastic lymph node, metastatic carcinoma not identified.
- C. Lymph node, R4, excision:
Metastatic poorly differentiated adenocarcinoma with focal areas of capsular penetration.
- D. Lung, right upper lobectomy:
Poorly differentiated adenocarcinoma.
Histologic grade: Poorly differentiated.
Tumor size: 1.7 cm.
Lymph node involvement: Metastatic poorly differentiated adenocarcinoma to 2 cm peribronchial lymph node.
Angiolymphatic invasion: Present (positive nodes)
Margins: Margins are uninvolved (negative), 1.5 cm from bronchial margin.
Pleural involvement: Carcinoma extending up to pleura without overt pleural infiltration.
Obstructive pneumonia: Absent.
AJCC: pT1N2MX; stage IIIA.
- E. Mediastinum, anterior, mass, excision:
Metastatic poorly differentiated adenocarcinoma
- F. Lymph node, R2, excision:
Hyperplastic lymph node with non-caseating granulomata.
Acid fast and fungal stains pending, to be subject of addendum report.

Note: The patient's history of breast carcinoma is noted. The positive TTF-1 immunohistochemical stain performed on the core biopsy of the lung tumor essentially confirms a pulmonary primary and

[page 2 of 4]
Data Date-Time: [REDACTED]

Printed By: [REDACTED]

Printed On: [REDACTED]

Order Name:

Observation Date-time: [REDACTED]

Result Name: Path Report

Result Status:

Final Result

excludes a breast primary carcinoma.

Electronically Signed Out By [REDACTED]

Date Reported: [REDACTED]

2 of 4

MACROSCOPIC DESCRIPTION

The specimens are submitted in six containers.

A. The first specimen is received fresh labeled lymph node level 7 and consists of multiple fragments of tan-brown soft tissue measuring 3 x 2.5 x 0.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED] study. The remainder of the specimen is submitted in toto.

B. The second specimen is received fresh labeled lymph node level 12 and consists of multiple fragments of tan-brown soft tissue measuring 2 x 1.5 x 0.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED] study. The remainder of the specimen is submitted in toto.

C. The third specimen is received fresh labeled lymph node #4 and consists of multiple fragments of tan-brown soft tissue measuring 2.5 x 2 x 1 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED] study. The largest fragment is bisected. The specimen is submitted in toto.

D. [REDACTED] reviewed the specimen and supervised the processing. The fourth specimen is received fresh labeled right upper lobe lung and consists of a lobectomy specimen measuring 12 x 11 x 5 cm and weighing 171 grams. The bronchial and vascular margins are removed and submitted. Directly adjacent to the main bronchus is a nodule measuring approximately 2 cm in diameter. This nodule may represent a lymph node. This possible lymph node is serially sectioned and submitted in toto. Sectioning the lung reveals one pale tan mass measuring approximately 1.7 x 1.5 x 1.5 cm. This mass abuts the pleura, however, it does not appear to grossly involve the pleura. The mass comes to within 3.5 cm of the bronchial/vascular margins. A representative portion of the mass is submitted for the SPCK study. The remainder of the mass is submitted in toto for permanent sections. Sectioning the remainder of the lung reveals no additional abnormalities. A random representative section of normal appearing lung is submitted for the [REDACTED] study. Normal appearing lung is also submitted for permanent sections.

E. The fifth specimen is received fresh labeled anterior mediastinal mass and consists of multiple fragments of tan-brown soft tissue measuring 1.5 x 1 x 0.5 cm in aggregate. A small portion of

[page 3 of 4]
Data Date-Time: [REDACTED]

Printed By: [REDACTED]
Printed On: [REDACTED]

Order Name:
Result Name: Path Report

Observation Date-time: [REDACTED]
Result Status: Final Result

the specimen is submitted for the [REDACTED] study. The remainder of the specimen is submitted in toto.

F. The sixth specimen is received fresh labeled lymph node R2 and consists of multiple fragments of tan-brown soft tissue measuring 3 x 2.5 x 1.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED] study. The remainder of the specimen is submitted in toto.

3 of 4

- Sections:
- A. Lymph node level 1, all
- B. Lymph node level 12, all
- C. Lymph node R4, all
- D1. Bronchial and vascular margins
- D2. D4. Lymph node
- D5. D7. Mass
- D8. & D9. Normal appearing lung
- E. Anterior mediastinal mass, all
- F1. & F2. Lymph node R2, all

MICROSCOPIC DESCRIPTION

Slides: 15 H & E

Simultaneously performed controls verified the reliability of the staining procedure(s).

A. The first portion of the specimen is a hyperplastic lymph node, exhibiting anthracosis and sinus histiocytosis. Metastatic carcinoma is not identified.

B. The second portion of the specimen is also a hyperplastic anthracotic lymph node. Metastatic carcinoma is not identified.

C. The third portion of the specimen is a sclerotic lymph node, which is infiltrated by metastatic carcinoma. The tumor is composed of infiltrating cords and nests of neoplastic cells having pleomorphic and hyperchromatic nuclei. The carcinoma is similar histologically to the primary carcinoma in the lung. There is probable focal capsular penetration. Most of the lymph node has been replaced with carcinoma extending contiguously over areas of 1 cm.

D. The bronchial and vascular margins are free of carcinoma. The tumor mass described grossly is an infiltrating non-small cell carcinoma composed of infiltrating cords and nests of neoplastic cells having pleomorphic and hyperchromatic nuclei. Mitoses are frequent, averaging at least one mitoses per high powered field in most areas. Although fairly poorly differentiated, the cell morphology would favor an adenocarcinoma. A mild lymphohistiocytic inflammatory response is present. The carcinoma extends up to the pleura where there may be

[page 4 of 4]
Data Date-Time: [REDACTED]

Printed By: [REDACTED]
Printed On: [REDACTED]

Order Name:
Result Name: Path Report

Observation Date-time: [REDACTED]
Result Status: Final Result

some superficial infiltration of the pleural fibrous tissue, although definite or overt infiltration into or through the pleura is not identified. In focal areas, there is tubular and glandular formation confirming the cell type as an adenocarcinoma. The surrounding lung does not exhibit obstructive pneumonia. The suspected lymph node noted grossly is a mass of carcinoma. There is a peripheral border of lymphoid tissue focally consistent with the remnant of a peribronchial lymph node. This represents a lymph node metastasis.

4 of 4

E. The fifth portion of the specimen is a lymph node, which is partially replaced by metastatic carcinoma similar to that described above.

F. The last portion of the specimen is a hyperplastic lymph node. Metastatic carcinoma is not identified. Non-caseating granulomata are present, which can be observed in nodes draining malignant tumors. Sarcoidosis would remain in the differential. ((END OF REPORT))

PRELIMINARY REPORT

Addendum Date Ordered: [REDACTED] Status: [REDACTED]
Date Complete: [REDACTED] By: [REDACTED]
Date Reported: [REDACTED]

Addendum Diagnosis
(Not Entered)

Addendum Comment
Acid fast and fungal stains are negative within the nodes containing non-caseating granulomata.

Comments

Result Comments

Requisition Comments:

Source: NCI Genomic Data Commons file cbe9c824-3485-4efd-86c9-364fa8d523d8 (TCGA-49-6761.73669CBA-81EE-4215-A938-32556C5A211A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).